Somatic mutation profile of tumor specimen TCGA-RE-A7BO-01A (aliquot TCGA-RE-A7BO-01A-11D-A33E-09) from TCGA case TCGA-RE-A7BO, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.1 years (26,348 days).
Specimen TCGA-RE-A7BO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0695bd65-8748-4396-b47b-f3fa238895fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RE-A7BO-10A (Blood Derived Normal), aliquot TCGA-RE-A7BO-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cdbcfc2-2cfc-435b-b1f3-ea1824983b1b

The open-access MAF lists 228 somatic variants for this specimen: 167 protein-altering or splice-affecting, 54 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 54, Nonsense Mutation 6, Intron 3, Splice Site 2, Frame Shift Del 2, 3'UTR 2, Frame Shift Ins 1, Nonstop Mutation 1, 3'Flank 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NAP1L3 | c.1505A>C p.K502T | Missense Mutation (SNP) | VAF 19/33 reads (58%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV59073839, COSV59074072, COSV59075074; called by muse, mutect2, varscan2
- RNF213 | c.12037G>A p.D4013N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.405); catalogued as rs397514563, CM1111820, COSV100300800; ClinVar: likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- ALX1 | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57494229; called by muse, mutect2, varscan2
- ALX1 | c.447A>T p.K149N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs1181179187; called by muse, mutect2, varscan2
- ANGPT1 | c.530T>G p.L177R | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99864966; called by muse, mutect2, varscan2
- ARCN1 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1393612239; called by muse, mutect2, varscan2
- CFAP53 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs373884778, COSV68352827; called by muse, mutect2, varscan2
- COL1A2 | c.2099G>C p.G700A | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM070828; called by muse, mutect2, varscan2
- COL6A3 | c.2756C>T p.A919V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs115327470, COSV55089446; ClinVar: benign / uncertain significance; called by mutect2, varscan2
- COQ4 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200009624, COSV55958190; called by muse, mutect2, varscan2
- CSMD1 | c.968A>C p.K323T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV68182293; called by muse, mutect2, varscan2
- DLG2 | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs758561562; called by muse, mutect2, varscan2
- DNAH11 | c.9359T>C p.L3120P | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60971292; called by muse, mutect2, varscan2
- DPYS | c.1271A>C p.N424T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV60911949; called by muse, mutect2, varscan2
- EYS | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs756552382, COSV60978209; called by muse, mutect2, varscan2
- EZHIP | c.1139C>A p.A380D | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV57955455; called by muse, mutect2, varscan2
- FGF5 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs201557946; called by muse, mutect2, varscan2
- FLG | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs139321371, COSV100910484; called by muse, mutect2, varscan2
- GGCX | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.717); catalogued as rs568608275, COSV52088543; called by muse, mutect2, varscan2
- GPR45 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.557); catalogued as rs1352198171, COSV51523131; called by muse, mutect2, varscan2
- GRIA2 | c.645A>T p.K215N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV52385939; called by muse, mutect2, varscan2
- GRIA4 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.372); catalogued as rs763888983, COSV56884103, COSV99233797; called by muse, mutect2, varscan2
- HPS4 | c.1096_1098del p.E366del | In Frame Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs761480950; called by pindel, varscan2
- IGKV1D-42 | c.222A>C p.K74N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs752306072; called by muse, mutect2, varscan2
- IGKV3-7 | c.58A>G p.R20G | Missense Mutation (SNP) | VAF 109/280 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1369325888; called by muse, mutect2, varscan2
- INTS9 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as rs946573655; called by muse, mutect2, varscan2
- KIAA0753 | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs755537723; called by muse, mutect2, varscan2
- KLHL24 | c.1638A>G p.I546M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs754246236; called by muse, mutect2, varscan2
- LRIG3 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762876825, COSV104413600; called by muse, mutect2, varscan2
- MAGEB18 | c.498A>C p.E166D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57463531; called by muse, mutect2, varscan2
- MAGEB2 | c.105A>C p.E35D | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV66781147; called by muse, mutect2, varscan2
- MED13L | c.4520G>A p.R1507H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs774267211; called by muse, mutect2, varscan2
- MLLT10 | c.1937G>T p.R646I (on ENST00000307729 / NM_001195626.3; = p.R662I on NM_004641.3) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV57003400; called by muse, mutect2, varscan2
- MRGPRX1 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.117); catalogued as rs1255784076, COSV57109805; called by muse, mutect2, varscan2
- MTUS2 | c.1242T>G p.I414M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV70913694; called by muse, mutect2, varscan2
- MUC15 | c.775T>G p.L259V | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV99846387; called by muse, mutect2, varscan2
- MUC16 | c.21386T>G p.L7129R | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.047); catalogued as COSV101197871; called by muse, mutect2, varscan2
- MUC16 | c.18570T>G p.D6190E | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.065); catalogued as rs761713163; called by muse, mutect2, varscan2
- MXRA5 | c.1926A>C p.Q642H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.078); catalogued as COSV54232610; called by muse, mutect2, varscan2
- NCBP3 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs773424380, COSV50106316; called by muse, mutect2, varscan2
- OR2M4 | c.625T>C p.F209L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as COSV100141352, COSV60709775, COSV60709879; called by muse, mutect2, varscan2
- OR4C16 | c.624T>G p.S208R | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV58944296; called by muse, mutect2, varscan2
- OR4P4 | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV58921012; called by muse, mutect2, varscan2
- OTOGL | c.2506A>C p.T836P (on ENST00000547103; = p.T827P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV72006544; called by muse, mutect2, varscan2
- P2RY13 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV99853628; called by muse, mutect2, varscan2
- PCDH15 | c.1892T>G p.V631G | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV100212884, COSV100215117; called by muse, mutect2, varscan2
- PCDH9 | c.3714A>C p.*1238Yext*26 (on ENST00000377865 / NM_203487.3; = p.*1204Yext*26 on NM_020403.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV60531117, COSV60535317, COSV60559707; called by muse, mutect2, varscan2
- PFKFB3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | PolyPhen benign (0.034); catalogued as rs140784797; called by muse, mutect2, varscan2
- PKD1 | c.9148G>A p.A3050T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768295964; called by muse, mutect2, varscan2
- PLEC | c.2801G>A p.R934H (on ENST00000322810 / NM_201380.4; = p.R824H on NM_000445.5) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1331262541; called by muse, mutect2
- PRKG1 | c.1787A>C p.K596T | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV64768507, COSV64771842; called by muse, mutect2, varscan2
- PRRX1 | c.673G>C p.A225P | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53416191; called by muse, mutect2, varscan2
- RECQL5 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs766459582; called by muse, varscan2
- RMDN1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52206039; called by muse, varscan2
- RTN1 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774510449, COSV50724648; called by muse, mutect2, varscan2
- SCN10A | c.4343A>C p.K1448T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV71860120; called by muse, mutect2, varscan2
- SCN4A | c.2054C>T p.T685M | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs140022722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.3208T>G p.L1070V (on ENST00000303354; = p.L1059V on NM_002977.3) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57603996; called by muse, mutect2, varscan2
- SETBP1 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.853); catalogued as COSV56312002; called by muse, mutect2, varscan2
- SLC44A5 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as rs1035423901, COSV100901722; called by muse, mutect2, varscan2
- SORCS3 | c.3383T>G p.L1128R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63808607; called by muse, mutect2, varscan2
- SPART | c.1242A>C p.K414N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as COSV62086373; called by muse, mutect2, varscan2
- STYK1 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs778653950; called by muse, mutect2, varscan2
- SYNE1 | c.21518T>G p.L7173R (on ENST00000367255 / NM_182961.4; = p.L7102R on NM_033071.3) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99548860; called by muse, mutect2, varscan2
- TAS2R60 | c.320C>A p.T107N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60330959; called by muse, mutect2, varscan2
- TECRL | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV101168657; called by muse, mutect2, varscan2
- TENM3 | c.3934G>T p.G1312* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV69301007; called by muse, mutect2, varscan2
- TIMP3 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56662061; called by muse, mutect2, varscan2
- TLR4 | c.1492T>G p.L498V (on ENST00000355622 / NM_138554.5; = p.L458V on NM_003266.4) | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923526; called by muse, mutect2, varscan2
- TRIM22 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762728519; called by muse, mutect2, varscan2
- TRPM1 | c.1606G>A p.V536M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779702766, COSV56637972; called by muse, mutect2, varscan2
- TTN | c.66607A>C p.T22203P (on ENST00000591111; = p.T14779P on NM_003319.4) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | PolyPhen possibly damaging (0.731); catalogued as rs753837961; called by muse, mutect2, varscan2
- UNC13C | c.1637T>G p.L546R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs768743988, COSV52845905, COSV52871720; called by muse, mutect2, varscan2
- USP35 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1338149382, COSV101489100; called by muse, mutect2, varscan2
- VCP | c.1618A>G p.I540V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs765061140; called by muse, mutect2, varscan2
- WFDC1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as COSV54745182; called by muse, mutect2, varscan2
- XDH | c.3938A>C p.K1313T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101051865; called by muse, mutect2, varscan2
- ZNF208 | c.2807A>T p.K936M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV101237161, COSV68101234, COSV68109514; called by muse, mutect2, varscan2
- ZNF208 | c.1715A>C p.K572T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68107459; called by muse, mutect2, varscan2
- ZNF486 | c.603A>C p.K201N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs1555718178, COSV58723355; called by muse, mutect2, varscan2
- ZNF98 | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV63335342, COSV63340837; called by muse, mutect2, varscan2
- AGMO | c.732T>G p.D244E | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AIDA | c.736T>C p.Y246H | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKT3 | c.1252-28_1257del p.X418_splice | Splice Site (DEL) | VAF 24/74 reads (32%) | called by mutect2, pindel
- ANKRD11 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARID1A | c.2489dup p.G831Rfs*41 | Frame Shift Ins (INS) | VAF 18/41 reads (44%) | called by mutect2, pindel, varscan2
- BIRC6 | c.12175G>T p.E4059* | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | called by muse, mutect2, varscan2
- C6 | c.1163A>C p.N388T | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CABIN1 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHRM3 | c.288C>G p.N96K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC1B | c.316T>C p.W106R | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNTN4 | c.83T>G p.F28C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRB1 | c.1615A>C p.S539R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CRMP1 | c.949T>G p.L317V | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CYP7B1 | c.1357T>G p.F453V | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- DCLK3 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX18 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- DDX18 | c.593_594del p.G198Vfs*6 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- ETS1 | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- EVC | c.1562A>G p.Q521R | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- FGB | c.1405A>C p.N469H | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- FLG2 | c.5900T>C p.V1967A | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- FPGS | c.1057C>T p.L353F | Missense Mutation (SNP) | VAF 47/69 reads (68%) | SIFT tolerated (0.69); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- FXR1 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNG8 | c.53T>A p.L18Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- GRM5 | c.1316A>G p.E439G | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2
- GTF3C1 | c.3938C>T p.S1313F | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HCFC2 | c.1774A>T p.K592* | Nonsense Mutation (SNP) | VAF 56/154 reads (36%) | called by muse, mutect2, varscan2
- HMCN1 | c.5455G>T p.E1819* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- KDM6A | c.675A>C p.K225N | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF21A | c.2135A>C p.E712A (on ENST00000361418 / NM_001378440.1; = p.E699A on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2
- KIF26A | c.2842C>A p.L948M | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC4C | c.949A>C p.K317Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- MINAR1 | c.1125A>C p.E375D | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- MKNK1 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MMP20 | c.730A>G p.M244V | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.17381A>C p.N5794T | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NIPBL | c.620C>G p.S207* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- NOD2 | c.988C>A p.P330T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOD2 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4A5 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- OR4C11 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR51B2 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.35); called by mutect2, varscan2
- OR5D16 | c.58T>G p.S20A | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- OR5D18 | c.424T>A p.C142S | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- P2RY10 | c.911T>A p.L304H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PCDHB10 | c.1551G>T p.R517S | Missense Mutation (SNP) | VAF 64/115 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PDHA2 | c.135A>C p.E45D | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PHLPP1 | c.2105A>G p.H702R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PIWIL1 | c.803A>G p.D268G | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PJA1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- PKHD1L1 | c.744T>G p.S248R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- PLA2R1 | c.3601G>C p.E1201Q | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- PTPRD | c.2729A>C p.E910A | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PXDN | c.3407A>C p.N1136T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- RALGAPB | c.3391C>G p.L1131V | Missense Mutation (SNP) | VAF 72/105 reads (69%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RBM12 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR3 | c.9743T>G p.L3248R (on ENST00000389232; = p.L3249R on NM_001036.6) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SCN9A | c.4100G>T p.R1367L (on ENST00000303354; = p.R1356L on NM_002977.3) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC1A2 | c.893G>C p.G298A | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); called by muse, mutect2
- SLC39A14 | c.1153T>G p.F385V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- SLITRK3 | c.1824A>C p.E608D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- SMAD4 | c.1604_1610del p.L535Pfs*15 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- SORCS3 | c.2234G>T p.C745F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPINDOC | c.1077C>G p.D359E | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPRYD7 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SRPK2 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- STAB1 | c.2628+2T>C p.X876_splice | Splice Site (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- SYNE1 | c.20875G>C p.D6959H (on ENST00000367255 / NM_182961.4; = p.D6888H on NM_033071.3) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.16459T>G p.L5487V (on ENST00000367255 / NM_182961.4; = p.L5416V on NM_033071.3) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R46 | c.124T>A p.S42T | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TET1 | c.1071A>C p.E357D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TEX14 | c.3119A>C p.E1040A (on ENST00000240361 / NM_001201457.2; = p.E1034A on NM_031272.5) | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.041); called by muse, mutect2
- TGDS | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAM1L1 | c.904T>C p.S302P | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.718); called by muse, varscan2
- TRIM58 | c.1372T>G p.L458V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TTN | c.63787A>C p.T21263P (on ENST00000591111; = p.T13839P on NM_003319.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TTN | c.15006A>C p.K5002N (on ENST00000591111; = p.K4075N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TTN | c.14122A>C p.S4708R (on ENST00000591111; = p.S3781R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- VPS35L | c.1471A>G p.K491E | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WDR17 | c.1232C>A p.T411K | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF486 | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF521 | c.887T>C p.L296P | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF578 | c.1418A>C p.H473P | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF585B | c.1273T>G p.L425V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ZNF804B | c.2545A>C p.T849P | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.2756A>G p.E919G | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ABCA8 | c.1965C>T p.C655= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs781158837, COSV52194068; called by muse, mutect2, varscan2
- ARHGAP20 | c.2776A>C p.R926= | Silent (SNP) | VAF 25/201 reads (12%) | called by muse, mutect2, varscan2
- ATP6V1B2 | c.54C>T p.P18= | Silent (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- BIRC6 | c.1866G>T p.L622= | Silent (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- C16orf78 | c.72A>G p.E24= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV54556863; called by muse, mutect2, varscan2
- C6orf118 | c.525A>G p.E175= | Silent (SNP) | VAF 20/32 reads (63%) | called by muse, mutect2, varscan2
- CD300LF | c.204C>T p.T68= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as rs144991054; called by muse, mutect2, varscan2
- CDH12 | c.1281T>C p.D427= | Silent (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- CDKL5 | c.2862T>C p.L954= | Silent (SNP) | VAF 43/79 reads (54%) | called by muse, mutect2, varscan2
- CNTN3 | c.1080A>G p.L360= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs1203888272; called by muse, mutect2, varscan2
- CTNNA3 | c.198T>G p.T66= | Silent (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1269C>T p.Y423= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- DGKI | c.2766A>G p.P922= | Silent (SNP) | VAF 33/174 reads (19%) | catalogued as COSV55978164; called by muse, mutect2, varscan2
- DGKK | c.399G>A p.S133= | Silent (SNP) | VAF 37/63 reads (59%) | catalogued as rs782553959, COSV101053170; called by muse, mutect2, varscan2
- EIF3E | c.231G>A p.V77= | Silent (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- FAT3 | c.7944C>T p.A2648= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as rs773625640; called by muse, mutect2, varscan2
- FLG | c.5607T>C p.R1869= | Silent (SNP) | VAF 50/139 reads (36%) | called by muse, varscan2
- FSHR | c.897A>G p.Q299= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100437660, COSV58623202; called by muse, mutect2, varscan2
- GPR26 | c.717C>T p.A239= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- GTSF1L | c.393G>A p.T131= | Silent (SNP) | VAF 38/53 reads (72%) | catalogued as rs375809336; called by muse, mutect2, varscan2
- HBE1 | c.210T>G p.T70= | Silent (SNP) | VAF 51/144 reads (35%) | catalogued as rs202129332, COSV53079805, COSV53080603; called by muse, mutect2, varscan2
- HDX | c.1596A>G p.E532= | Silent (SNP) | VAF 43/82 reads (52%) | catalogued as COSV52978701; called by muse, mutect2, varscan2
- HPS1 | c.1176C>G p.A392= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as rs370108188; called by muse, mutect2, varscan2
- IRAG1 | c.591C>A p.L197= | Silent (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- ITGA9 | c.2484T>C p.S828= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs1230882184; called by muse, mutect2, varscan2
- ITPRID1 | c.90G>A p.A30= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs771087429; called by muse, mutect2, varscan2
- KRT6B | c.1440C>T p.G480= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as rs373899186, COSV99360464; called by muse, mutect2, varscan2
- LRP1B | c.2799T>A p.S933= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV101259999; called by muse, mutect2, varscan2
- LRRN3 | c.19C>A p.R7= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV57817640; called by muse, mutect2, varscan2
- LRSAM1 | c.684C>A p.I228= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV55938604; called by muse, mutect2, varscan2
- MANEA | c.156T>C p.T52= | Silent (SNP) | VAF 11/97 reads (11%) | called by muse, mutect2, varscan2
- MBOAT1 | c.453C>T p.T151= | Silent (SNP) | VAF 66/109 reads (61%) | called by muse, mutect2, varscan2
- MUC16 | c.14472G>A p.T4824= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs751538389, COSV67457476; called by muse, mutect2, varscan2
- MYO7A | c.1671C>T p.I557= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs373108550; called by muse, mutect2, varscan2
- OR4C15 | c.735T>C p.T245= (on ENST00000314644; = p.T191= on NM_001001920.2) | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV58951027; called by muse, mutect2, varscan2
- OR6B1 | c.225T>C p.S75= | Silent (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- PCDH11X | c.2862T>C p.T954= | Silent (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- PCDHA4 | c.1614C>T p.R538= | Silent (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.1332C>T p.D444= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- PLXNA2 | c.81G>A p.L27= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs1358420261; called by muse, mutect2, varscan2
- PRB2 | c.822T>C p.P274= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as rs762799958, COSV66983048, COSV66983544; called by muse, mutect2, varscan2
- PREX2 | c.4134A>G p.K1378= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV55772082, COSV55807968; called by muse, mutect2, varscan2
- PRKCB | c.120C>T p.T40= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1487689045; called by mutect2, varscan2
- RBMXL2 | c.729C>T p.Y243= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs751190048, COSV60980900; called by muse, mutect2, varscan2
- RSPH6A | c.561C>A p.A187= | Silent (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
- SLC11A1 | c.1032C>T p.D344= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs774591069; called by muse, mutect2, varscan2
- SLC2A12 | c.804G>C p.L268= | Silent (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- SLC35F3 | c.1263C>T p.R421= (on ENST00000366617 / NM_001300845.1; = p.R490= on NM_173508.4) | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- SLF1 | c.2145G>A p.L715= | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- SLITRK5 | c.2664T>G p.T888= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- SULT1A1 | c.42C>T p.Y14= | Silent (SNP) | VAF 24/180 reads (13%) | catalogued as rs763159213, COSV59090471; called by muse, varscan2
- TRHDE | c.1881T>C p.T627= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV53852515; called by muse, mutect2, varscan2
- ZNF697 | c.1320C>T p.R440= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1228503265; called by muse, mutect2, varscan2
- ZNF880 | c.694A>C p.R232= | Silent (SNP) | VAF 43/77 reads (56%) | called by muse, mutect2, varscan2
- ANKRD20A5P | n.171C>T | RNA (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- RCC1 | c.-261-720_-261-690del | Intron (DEL) | VAF 13/88 reads (15%) | catalogued as rs758703972; called by mutect2, varscan2
- ST8SIA2 | chr15:92472376 A>G | 3'Flank (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- TRIOBP | c.6324+199G>T | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- UMODL1 | c.1900-71C>T | Intron (SNP) | VAF 16/65 reads (25%) | catalogued as rs765168915, COSV100210825; called by muse, mutect2, varscan2
- XIRP2 | c.*1160A>C | 3'UTR (SNP) | VAF 30/66 reads (45%) | catalogued as COSV99746577; called by muse, varscan2
- XIRP2 | c.*1223A>C | 3'UTR (SNP) | VAF 17/114 reads (15%) | catalogued as rs748818071; called by muse, varscan2
